Somatic mutation profile of tumor specimen TCGA-DX-A8BP-01A (aliquot TCGA-DX-A8BP-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BP, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 85.9 years (31,382 days).
Specimen TCGA-DX-A8BP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c93a4660-f8fc-455b-99a0-9c0af0c17808.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BP-10A (Blood Derived Normal), aliquot TCGA-DX-A8BP-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccbe9c16-eb72-451a-a5a1-6fb1cb0be36e

The open-access MAF lists 804 somatic variants for this specimen: 523 protein-altering or splice-affecting, 259 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 478, Silent 259, Nonsense Mutation 21, Splice Site 14, Intron 10, Splice Region 6, RNA 5, 3'UTR 3, 5'UTR 2, 3'Flank 2, Translation Start Site 2, In Frame Del 2.

Variants (750 of 804; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L12 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.796); catalogued as rs1057519880, COSV55862483; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.7981C>T p.R2661* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as rs149070832; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDUA | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121965029, CM950677, COSV99926580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 15/27 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3403C>T p.H1135Y (on ENST00000404938 / NM_001163941.2; = p.H690Y on NM_178559.6) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99330132; called by muse, mutect2, varscan2
- AC100868.1 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1257628043, COSV51837967; called by muse, mutect2, varscan2
- ACAN | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100719453; called by muse, mutect2, varscan2
- ACAN | c.4882G>A p.G1628R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61358176; called by muse, mutect2, varscan2
- ACER1 | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV56835292; called by muse, mutect2, varscan2
- ACTB | c.1067G>T p.W356L | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100080015; called by muse, mutect2, varscan2
- ADAM21 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.02); catalogued as rs762521545, COSV50809100; called by muse, mutect2, varscan2
- ADAMTS14 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100941952; called by muse, mutect2, varscan2
- ADAMTS17 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV99172712; called by muse, mutect2, varscan2
- ADAMTS17 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.114); catalogued as COSV51475830; called by muse, mutect2, varscan2
- ADAMTS20 | c.4832G>A p.R1611K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs561936298, COSV101240554, COSV67133016; called by muse, mutect2, varscan2
- ADCK1 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99452918; called by muse, mutect2, varscan2
- ADCY8 | c.2687G>A p.G896E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99654977; called by muse, mutect2, varscan2
- ADGRA3 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1338263672, COSV99293901; called by muse, mutect2, varscan2
- ADGRE1 | c.2222+1G>A p.X741_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as rs1378587049, COSV99166032; called by muse, mutect2, varscan2
- ADGRF4 | c.1570G>A p.G524R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349189; called by muse, mutect2, varscan2
- ADGRF5 | c.2812A>G p.I938V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.316); catalogued as COSV99346659; called by muse, mutect2
- ADGRG4 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54962282; called by muse, mutect2, varscan2
- AHNAK | c.3684T>A p.D1228E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.036); catalogued as COSV99950188; called by muse, mutect2, varscan2
- AKNA | c.3917C>T p.P1306L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV99801259; called by muse, mutect2
- AKNA | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs368698649, COSV56311502, COSV99800701; called by muse, mutect2, varscan2
- AL121899.2 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101198717; called by muse, mutect2, varscan2
- ALDH8A1 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665095; called by muse, mutect2, varscan2
- ANKFY1 | c.3079C>G p.L1027V (on ENST00000341657 / NM_001330063.2; = p.L1028V on NM_016376.5) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV100493307; called by muse, mutect2, varscan2
- ANKRD34A | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV100041464; called by muse, mutect2, varscan2
- ANO3 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.98); catalogued as COSV99846744; called by muse, mutect2, varscan2
- ANO5 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs770013241, COSV100202373, COSV61082862; called by muse, mutect2, varscan2
- AP1G2 | c.929C>G p.A310G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); catalogued as COSV99846355, COSV99846389; called by muse, mutect2, varscan2
- APOB | c.2522G>A p.G841E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245396413, COSV99268724; called by muse, mutect2, varscan2
- APOD | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751722415, COSV100581161; called by muse, mutect2, varscan2
- AQP12A | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100539043; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP35 | c.3992C>T p.P1331L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101351946; called by muse, mutect2, varscan2
- ARHGAP5 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV100565752; called by muse, mutect2, varscan2
- ARID1A | c.3662T>G p.M1221R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100253935, COSV61390768; called by muse, mutect2, varscan2
- AS3MT | c.1021-1G>T p.X341_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100185824; called by muse, mutect2, varscan2
- ASB16 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV99519094; called by muse, mutect2, varscan2
- ASH1L | c.5044C>T p.P1682S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100853649, COSV104428100; called by muse, mutect2
- ASTN2 | c.1637G>A p.R546K (on ENST00000313400 / NM_001365069.1; = p.R495K on NM_014010.5) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100531157; called by muse, mutect2
- ATAD2B | c.1756A>T p.T586S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99478704; called by muse, mutect2, varscan2
- ATAD5 | c.3934G>A p.D1312N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100429649, COSV100430302; called by muse, mutect2, varscan2
- ATG13 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100366133; called by muse, mutect2, varscan2
- BACE2 | c.782G>C p.G261A | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100161250; called by muse, mutect2
- BAIAP2L1 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.677); catalogued as COSV99135111; called by muse, mutect2, varscan2
- BFSP2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV56588805; called by muse, mutect2, varscan2
- BICRA | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1189063999, COSV101194515; called by muse, mutect2
- BMP15 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53142576; called by muse, mutect2, varscan2
- C12orf4 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV54206898; called by muse, mutect2, varscan2
- C19orf53 | c.181A>C p.I61L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV99684351; called by muse, mutect2, varscan2
- C19orf57 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as COSV60967034; called by muse, mutect2
- C1orf127 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100983526; called by muse, mutect2, varscan2
- C1orf189 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201047185; called by muse, mutect2, varscan2
- C5orf34 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs199593005, COSV100175662; called by muse, mutect2, varscan2
- CACNB4 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99139928; called by muse, mutect2, varscan2
- CACNG4 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100048004; called by muse, mutect2
- CADPS | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.996); catalogued as COSV51872626, COSV99341566; called by muse, mutect2, varscan2
- CADPS2 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV100465269, COSV100466766; called by muse, mutect2, varscan2
- CAPN7 | c.1789-1G>A p.X597_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as rs1277513097, COSV99513113; called by muse, mutect2, varscan2
- CARD8 | c.809A>G p.H270R (on ENST00000651546 / NM_001184900.3; = p.H220R on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100751283; called by muse, mutect2, varscan2
- CARNS1 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371868488; called by muse, mutect2, varscan2
- CCDC116 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1314575946, COSV99489540; called by muse, mutect2, varscan2
- CCDC178 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV55783133, COSV55799572; called by muse, mutect2, varscan2
- CCDC40 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99482308; called by muse, mutect2
- CCDC88B | c.1783A>G p.R595G | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100106088; called by muse, mutect2, varscan2
- CD300LG | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99517679; called by muse, mutect2, varscan2
- CDH7 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775706781, COSV59884116; called by muse, mutect2, varscan2
- CDS1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs751177183, COSV99881054, COSV99881217; called by muse, mutect2, varscan2
- CECR2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV99378081; called by muse, mutect2, varscan2
- CELA3B | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs777058590, COSV100448904; called by muse, mutect2, varscan2
- CENPF | c.8485G>A p.G2829S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV100872085; called by muse, mutect2, varscan2
- CEP131 | c.2767G>A p.E923K (on ENST00000269392 / NM_001319228.2; = p.E920K on NM_014984.4) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs577025986, COSV53950529; called by muse, mutect2, varscan2
- CFAP100 | c.1202A>G p.N401S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100729487; called by muse, mutect2, varscan2
- CFAP45 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63648513; called by muse, mutect2, varscan2
- CFAP47 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as rs779460237, COSV99934292; called by muse, mutect2, varscan2
- CHAD | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.088); catalogued as COSV99366350; called by muse, mutect2, varscan2
- CHD5 | c.1934+1G>A p.X645_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99315511; called by muse, mutect2, varscan2
- CHD5 | c.1934G>A p.R645K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV99315513; called by muse, mutect2, varscan2
- CHD5 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99315517; called by muse, mutect2, varscan2
- CHRDL1 | c.1138C>T p.L380F (on ENST00000372045; = p.L386F on NM_145234.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.991); catalogued as COSV54323722, COSV54327547; called by muse, mutect2, varscan2
- CHRDL2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99734183; called by muse, mutect2, varscan2
- CIDEB | c.466T>G p.F156V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99351247; called by muse, mutect2, varscan2
- CIT | c.4865C>T p.S1622F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99951391; called by muse, mutect2, varscan2
- CLCN5 | c.1350C>T p.I450= | Splice Region (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100260472; called by muse, mutect2, varscan2
- CLEC4F | c.552G>C p.K184N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV55480649, COSV99714093, COSV99714102; called by muse, mutect2, varscan2
- CLPTM1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100494085; called by muse, mutect2, varscan2
- CLVS1 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs770762643, COSV100370878; called by muse, varscan2
- CNTN1 | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV100752023; called by muse, mutect2
- CNTNAP4 | c.3310C>T p.H1104Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100273772; called by muse, mutect2, varscan2
- COL11A1 | c.2746G>A p.G916S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100618360; called by muse, mutect2, varscan2
- COL4A4 | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100308001; called by muse, mutect2, varscan2
- COL5A3 | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs975939578, COSV99319989; called by muse, mutect2, varscan2
- COL6A3 | c.3787G>C p.D1263H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99802381; called by muse, mutect2, varscan2
- COPS2 | c.295A>T p.I99F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100157442, COSV100157455; called by muse, mutect2, varscan2
- CPNE6 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99393901; called by muse, mutect2, varscan2
- CR1 | c.5683G>A p.G1895R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV100888111; called by muse, mutect2, varscan2
- CSMD3 | c.9200G>A p.R3067K (on ENST00000297405 / NM_001363185.1; = p.R2898K on NM_052900.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV99843999; called by muse, mutect2, varscan2
- CSMD3 | c.2534G>A p.R845Q (on ENST00000297405 / NM_001363185.1; = p.R741Q on NM_052900.3) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754786650, COSV52123877, COSV52243892; called by muse, mutect2, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- CUL7 | c.3563G>A p.G1188E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54823146; called by muse, mutect2, varscan2
- CYP2J2 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.167); catalogued as COSV100967933; called by muse, mutect2, varscan2
- CYP4F8 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV57854931; called by muse, mutect2, varscan2
- DCC | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200830938; called by muse, mutect2, varscan2
- DENND4B | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100768961; called by muse, mutect2, varscan2
- DENND4B | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100768965; called by muse, mutect2, varscan2
- DEUP1 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99977763; called by muse, mutect2
- DGKD | c.2020G>A p.G674R (on ENST00000264057 / NM_152879.3; = p.G630R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV99897923; called by muse, mutect2, varscan2
- DICER1 | c.4678G>A p.A1560T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100602665; called by muse, mutect2, varscan2
- DKK2 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV99569665; called by muse, mutect2, varscan2
- DLGAP3 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV99333336; called by muse, mutect2, varscan2
- DLL3 | c.380G>A p.W127* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99219629; called by muse, mutect2, varscan2
- DNAH2 | c.11155G>A p.E3719K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV101209658; called by muse, mutect2, varscan2
- DNAH3 | c.10159G>A p.E3387K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54504699, COSV54505840; called by muse, mutect2, varscan2
- DNAH5 | c.11888C>T p.S3963L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs191057833, COSV54214570, COSV99445303; called by muse, mutect2, varscan2
- DNAH7 | c.5869C>T p.R1957* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as rs149212659, COSV56751897; called by muse, mutect2, varscan2
- DNAH9 | c.5224T>C p.Y1742H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV99308877; called by muse, mutect2, varscan2
- DNAJB11 | c.461T>A p.V154D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.24); catalogued as COSV99408788; called by muse, mutect2, varscan2
- DNAJC1 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100981444; called by muse, mutect2, varscan2
- DOCK3 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99815984; called by muse, mutect2, varscan2
- DPM2 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1338503253, COSV100072330; called by muse, mutect2, varscan2
- DPP10 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV59661325; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DRD2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100670279, COSV60755178; called by muse, mutect2, varscan2
- DSG2 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853655; called by muse, mutect2, varscan2
- DUOX1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.219); catalogued as COSV100368618; called by muse, mutect2, varscan2
- DYNC1H1 | c.7490C>T p.A2497V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100795584; called by muse, mutect2, varscan2
- DYNC1LI1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99818420; called by muse, mutect2, varscan2
- EBF3 | c.1433C>T p.P478L (on ENST00000355311 / NM_001375392.1; = p.P469L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100799735; called by muse, mutect2, varscan2
- EDEM2 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780339064, COSV100993805; called by muse, mutect2, varscan2
- EHMT1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100604430; called by muse, mutect2, varscan2
- EIF2AK4 | c.2773G>T p.D925Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775578; called by muse, mutect2, varscan2
- EIF2B3 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100838991; called by muse, mutect2
- EIF3L | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101094750; called by muse, mutect2, varscan2
- EIF4G2 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); catalogued as COSV101151200; called by muse, mutect2, varscan2
- ELAPOR2 | c.3031G>A p.E1011K (on ENST00000450689 / NM_001142749.3; = p.E844K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV51884232, COSV51888478; called by muse, mutect2, varscan2
- ELAPOR2 | c.2576C>T p.T859I (on ENST00000450689 / NM_001142749.3; = p.T692I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99789531; called by muse, mutect2, varscan2
- EP400 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100202580; called by muse, mutect2, varscan2
- EPPK1 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1554660093, COSV101599988; called by muse, mutect2, varscan2
- EPRS1 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100859548; called by muse, mutect2, varscan2
- EPX | c.2003G>A p.R668K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99836842; called by muse, mutect2, varscan2
- ERICH3 | c.4092G>C p.E1364D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV100446118, COSV58605180; called by muse, mutect2, varscan2
- F5 | c.4585G>A p.E1529K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV63121144; called by muse, mutect2, varscan2
- FAM160B1 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV100985625, COSV65087798; called by muse, mutect2, varscan2
- FAM193B | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.187); catalogued as COSV100286707, COSV100286901; called by muse, mutect2, varscan2
- FAT4 | c.1967C>T p.S656F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV101272929; called by muse, mutect2, varscan2
- FBN3 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); catalogued as rs151226812; called by muse, mutect2
- FBXL7 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs777808158, COSV100311186; called by muse, mutect2, varscan2
- FCER2 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs745635553, COSV100689684, COSV60917155; called by muse, mutect2, varscan2
- FCRL2 | c.504G>A p.W168* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100830033; called by muse, mutect2, varscan2
- FER1L5 | c.4355A>G p.Q1452R (on ENST00000623019; = p.Q1425R on NM_001293083.2) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV101208929; called by muse, mutect2, varscan2
- FLG | c.8507G>A p.S2836N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs777731067, COSV64240932; called by muse, mutect2
- FMNL2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.991); catalogued as COSV99981215; called by muse, mutect2, varscan2
- FMO2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99269395; called by muse, mutect2, varscan2
- FN1 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100118550, COSV60552664; called by muse, mutect2, varscan2
- FREM1 | c.2239G>T p.V747F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV101085737; called by muse, mutect2, varscan2
- FZR1 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV100553969; called by muse, mutect2, varscan2
- GABRG1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.489); catalogued as COSV99778956; called by muse, mutect2, varscan2
- GAD1 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV100713961, COSV60154151; called by muse, mutect2, varscan2
- GAD2 | c.1516T>C p.F506L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99394284; called by muse, mutect2, varscan2
- GALNTL5 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67180873; called by muse, mutect2, varscan2
- GALNTL6 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV101560673; called by muse, mutect2, varscan2
- GAPVD1 | c.2452C>T p.P818S (on ENST00000394104; = p.P845S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV99783934; called by mutect2, varscan2
- GAPVD1 | c.2453C>T p.P818L (on ENST00000394104; = p.P845L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as COSV99783935; called by mutect2, varscan2
- GBE1 | c.154T>C p.F52L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV101450376; called by muse, mutect2, varscan2
- GCC2 | c.3577C>T p.Q1193* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100565694; called by muse, mutect2, varscan2
- GCN1 | c.5659G>A p.A1887T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100326250; called by muse, mutect2, varscan2
- GGT5 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99571993; called by muse, mutect2
- GHSR | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV53841770; called by muse, mutect2, varscan2
- GLMP | c.931T>A p.Y311N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV99828202; called by muse, mutect2, varscan2
- GOLGA4 | c.3356C>T p.S1119F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as COSV100729233; called by muse, mutect2, varscan2
- GOLM1 | c.468G>A p.L156= | Splice Region (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99974538; called by muse, mutect2, varscan2
- GPR152 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100351710; called by muse, mutect2, varscan2
- GPR152 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); catalogued as COSV100351712; called by muse, mutect2, varscan2
- GRB10 | c.1508C>T p.S503F (on ENST00000398812; = p.S457F on NM_001001549.3) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1246214780, COSV60009606; called by muse, mutect2, varscan2
- GRIN2D | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54381026; called by muse, mutect2, varscan2
- GRM8 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV100283647, COSV100286884; called by muse, mutect2, varscan2
- GSTM5 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99860053; called by muse, mutect2, varscan2
- GTF3C3 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.077); catalogued as COSV99827120; called by muse, mutect2, varscan2
- GUCY1A1 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV99638896; called by muse, mutect2, varscan2
- GUCY2C | c.2157A>G p.E719= | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99664293; called by muse, mutect2, varscan2
- H3C2 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV52518947; called by muse, mutect2, varscan2
- H3C2 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV99451801; called by muse, mutect2, varscan2
- HAPLN1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99165257; called by muse, mutect2, varscan2
- HAS1 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV55787638, COSV55788774; called by muse, mutect2, varscan2
- HCLS1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.268); catalogued as COSV100101343; called by muse, mutect2, varscan2
- HERC1 | c.8875C>T p.P2959S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV101497092; called by muse, mutect2, varscan2
- HERC2 | c.4910G>A p.S1637N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55317762, COSV99877625; called by muse, mutect2, varscan2
- HK2 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs371320494; called by muse, mutect2, varscan2
- HPGDS | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754130316, COSV99756190; called by muse, mutect2, varscan2
- HRNR | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100914059; called by muse, mutect2, varscan2
- IGSF22 | c.2671G>A p.G891R (on ENST00000319338; = p.G992R on NM_173588.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1478206828, COSV99773911; called by muse, mutect2, varscan2
- IL18R1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as COSV99295566; called by muse, mutect2, varscan2
- ILKAP | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99611242; called by muse, mutect2, varscan2
- INPP5D | c.2749G>A p.G917R (on ENST00000445964 / NM_001017915.3; = p.G916R on NM_005541.5) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV64035701; called by muse, mutect2, varscan2
- INTS2 | c.3514G>A p.G1172R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.407); catalogued as COSV99249032; called by muse, mutect2, varscan2
- IPO13 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV54836810; called by muse, mutect2, varscan2
- IRF9 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs367862499; called by mutect2, varscan2
- ITGA1 | c.2022G>A p.M674I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs868105551, COSV50902649; called by muse, mutect2
- ITGAV | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV53710921; called by muse, mutect2
- ITIH2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV64435271; called by muse, mutect2, varscan2
- ITPR1 | c.6140C>T p.P2047L (on ENST00000354582; = p.P1992L on NM_002222.7) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100233694; called by muse, mutect2
- ITPR2 | c.6048T>A p.D2016E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101190289; called by muse, mutect2, varscan2
- JAG1 | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653619; called by muse, mutect2, varscan2
- JAG2 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs977973203, COSV100078969; called by muse, mutect2, varscan2
- JAK3 | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV101513048; called by muse, mutect2, varscan2
- KALRN | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53775298; called by muse, mutect2, varscan2
- KCNJ12 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100056414; called by muse, varscan2
- KCNV1 | c.931G>T p.V311F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99819263, COSV99819543; called by muse, mutect2, varscan2
- KEL | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs199731371, COSV62333799; called by muse, mutect2, varscan2
- KIDINS220 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs374716369; called by muse, mutect2, varscan2
- KIF21B | c.4714T>G p.W1572G (on ENST00000422435 / NM_001252100.2; = p.W1559G on NM_017596.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1486124253, COSV100145318; called by muse, mutect2, varscan2
- KIF7 | c.1982G>A p.R661K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV101068126; called by muse, mutect2, varscan2
- KLHL13 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.07); catalogued as rs759624828, COSV99452788; called by muse, mutect2
- KRT33B | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99290900; called by muse, mutect2, varscan2
- KRT76 | c.813G>A p.K271= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as COSV60120314; called by muse, mutect2, varscan2
- KRTAP9-9 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV101223560; called by muse, mutect2, varscan2
- LAMA3 | c.9269G>A p.R3090Q (on ENST00000313654 / NM_198129.4; = p.R1481Q on NM_000227.6) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs774817207, COSV52533782; called by muse, mutect2, varscan2
- LAMC1 | c.3761A>G p.H1254R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as rs770268047, COSV99280690; called by mutect2, varscan2
- LELP1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.045); catalogued as rs1455286943, COSV64202480; called by muse, mutect2, varscan2
- LMF2 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV99327847; called by muse, mutect2, varscan2
- LMOD1 | c.413G>T p.R138I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV100939303, COSV66172359; called by muse, mutect2, varscan2
- LRFN5 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53257090; called by muse, mutect2, varscan2
- LRP1B | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as COSV67222493; called by muse, mutect2, varscan2
- LRRC31 | c.1337T>C p.I446T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV52982340; called by muse, mutect2
- LRRC37A3 | c.4839A>C p.E1613D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV100141586; called by muse, mutect2, varscan2
- LRRC37A3 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV100141588; called by muse, mutect2, varscan2
- LRRTM4 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101297762; called by muse, mutect2
- LTBP1 | c.3254A>C p.Q1085P (on ENST00000404816 / NM_206943.4; = p.Q759P on NM_000627.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.366); catalogued as rs1393565021, COSV99699030; called by muse, mutect2, varscan2
- MACF1 | c.18029T>A p.M6010K (on ENST00000372915; = p.M4055K on NM_012090.5) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99247547; called by muse, mutect2, varscan2
- MACF1 | c.18817C>T p.H6273Y (on ENST00000372915; = p.H4318Y on NM_012090.5) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99247548; called by muse, mutect2, varscan2
- MAGEB18 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.936); catalogued as COSV57463376, COSV57465510; called by muse, mutect2, varscan2
- MAGI2 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV100836995; called by muse, mutect2, varscan2
- MAJIN | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV100104755; called by muse, mutect2
- MAOB | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1426305009, COSV100956292; called by muse, mutect2, varscan2
- MAP2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as COSV99562121; called by muse, mutect2, varscan2
- MAP4K1 | c.370-2A>C p.X124_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV50264884; called by muse, mutect2, varscan2
- MAPK10 | c.363G>A p.M121I (on ENST00000359221 / NM_001351625.2; = p.M159I on NM_002753.5) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as COSV100175747; called by muse, mutect2, varscan2
- MAPK6 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV99959554; called by muse, mutect2, varscan2
- MAPKBP1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99530368; called by muse, mutect2, varscan2
- MAST4 | c.4941T>A p.D1647E (on ENST00000403625 / NM_001164664.2; = p.D1458E on NM_015183.3) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as COSV99846402; called by muse, mutect2, varscan2
- MBD5 | c.2929C>T p.P977S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68698044; called by mutect2, varscan2
- MBOAT7 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV99825151; called by muse, mutect2, varscan2
- MCF2 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58476992; called by muse, mutect2, varscan2
- MCF2L | c.2995G>A p.G999R (on ENST00000375608; = p.G967R on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV56178370; called by muse, mutect2, varscan2
- MCRS1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100657447; called by muse, mutect2, varscan2
- MED20 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs144169919; called by muse, mutect2, varscan2
- MEGF9 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs779381765, COSV100879580; called by muse, mutect2
- METTL15 | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100328894; called by mutect2, varscan2
- MGAT3 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV100362113; called by muse, mutect2, varscan2
- MICALL2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs991414727, COSV99876364; called by muse, mutect2, varscan2
- MKRN3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100091812; called by muse, mutect2, varscan2
- MKRN3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58812571; called by muse, mutect2, varscan2
- MPO | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56568903; called by muse, mutect2, varscan2
- MS4A4A | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV100557984; called by muse, mutect2, varscan2
- MTNR1A | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100208365; called by muse, mutect2
- MUC16 | c.10819C>T p.P3607S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1469886297, COSV101202231; called by muse, mutect2, varscan2
- MUC17 | c.9373C>T p.L3125F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs1278601389, COSV100075597; called by muse, mutect2, varscan2
- MUC5AC | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); catalogued as COSV100650742; called by muse, mutect2, varscan2
- MUC5B | c.4197T>G p.C1399W | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101500948; called by muse, mutect2, varscan2
- MYC | c.175C>T p.P59S (on ENST00000377970; = p.P74S on NM_002467.6) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52367409, COSV52367643, COSV52370791; called by muse, mutect2, varscan2
- MYC | c.176C>T p.P59L (on ENST00000377970; = p.P74L on NM_002467.6) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294281543, COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2, varscan2
- MYH7 | c.3713T>G p.I1238S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV100806863; called by muse, mutect2, varscan2
- MYO1B | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs758864271, COSV58434481; called by muse, mutect2, varscan2
- MYO1F | c.3175G>C p.E1059Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100597190; called by muse, mutect2, varscan2
- MYO5C | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV99955836; called by muse, mutect2, varscan2
- MYO9B | c.3787C>T p.P1263S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as COSV101262033, COSV68278455; called by muse, mutect2
- NAA80 | c.662C>T p.P221L (on ENST00000417393 / NM_001200018.2; = p.P243L on NM_012191.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99807974; called by muse, mutect2
- NBEA | c.7741G>A p.D2581N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV100085094; called by muse, mutect2, varscan2
- NCEH1 | c.551C>T p.S184F (on ENST00000538775; = p.S144F on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99860498; called by muse, mutect2, varscan2
- NDST3 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs1362496121, COSV99632263; called by muse, mutect2, varscan2
- NEB | c.9808G>A p.A3270T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1560541262, COSV99429039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECAB3 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as COSV55778274, COSV99865266; called by muse, varscan2
- NF1 | c.4690C>T p.L1564F (on ENST00000358273 / NM_001042492.3; = p.L1543F on NM_000267.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.714); catalogued as rs1427435078, COSV100648513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIFK | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs761077196, COSV53534615; called by muse, mutect2, varscan2
- NLGN3 | c.1150C>T p.P384S (on ENST00000358741 / NM_181303.2; = p.P364S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1307562859, COSV100705130; called by muse, mutect2, varscan2
- NLRP12 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.049); catalogued as rs766680396, COSV100146090; called by muse, mutect2, varscan2
- NLRX1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV99425069; called by muse, mutect2, varscan2
- NOTCH1 | c.2467+1G>A p.X823_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as COSV53062155; called by muse, mutect2, varscan2
- NOTCH1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492727; called by muse, mutect2, varscan2
- NOTCH1 | c.404-1G>A p.X135_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV53025516; called by muse, mutect2, varscan2
- NOTCH4 | c.5740C>T p.R1914C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100901237, COSV66680278; called by muse, mutect2, varscan2
- NOTUM | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as rs762674545, COSV101293844; called by muse, mutect2, varscan2
- NPAS3 | c.1301+2T>C p.X434_splice (on ENST00000356141 / NM_001164749.2; = p.X402_splice on NM_022123.3) | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100640804, COSV60843804; called by muse, mutect2, varscan2
- NRIP1 | c.3181T>A p.L1061M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100013280; called by muse, mutect2, varscan2
- NUDCD2 | c.379T>A p.F127I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV100243739; called by muse, mutect2, varscan2
- NUGGC | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100429916; called by muse, mutect2, varscan2
- NUP54 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99345535; called by muse, mutect2, varscan2
- OMG | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99907966; called by muse, mutect2
- OR10A7 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100406647; called by muse, mutect2, varscan2
- OR11A1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs745945077, COSV65820876; called by muse, mutect2, varscan2
- OR11H12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1370242111, COSV73569293; called by muse, varscan2
- OR11L1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869509, COSV99053953; called by muse, mutect2, varscan2
- OR4A47 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.113); catalogued as COSV71444920, COSV71444953; called by muse, mutect2, varscan2
- OR4C15 | c.523C>T p.R175C (on ENST00000314644; = p.R121C on NM_001001920.2) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs267602969, COSV58951118, COSV58951281; called by muse, mutect2, varscan2
- OR4K13 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV100237948; called by mutect2, varscan2
- OR51B6 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66513221; called by mutect2, varscan2
- OR51F1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1162953353, COSV100598938, COSV58579283; called by muse, mutect2, varscan2
- OR52H1 | c.67G>A p.E23K (on ENST00000322653; = p.E29K on NM_001005289.1) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100497304; called by muse, mutect2, varscan2
- OR52N4 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100421565; called by mutect2, varscan2
- OR5A2 | c.782T>A p.M261K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV100119870; called by muse, mutect2, varscan2
- OR5P2 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV100271457; called by muse, mutect2, varscan2
- OR5P2 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100271461; called by muse, mutect2, varscan2
- OTUD7B | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64917502; called by muse, mutect2, varscan2
- PACS2 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100331078; called by muse, mutect2, varscan2
- PARVG | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796155; called by muse, mutect2, varscan2
- PCDHB10 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as rs782195305, COSV99505198; called by muse, mutect2, varscan2
- PCDHB6 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV50736353; called by muse, varscan2
- PCDHGA4 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as COSV53894825; called by muse, mutect2, varscan2
- PCDHGC5 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.194); catalogued as COSV99342951; called by muse, mutect2
- PCDHGC5 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs2233605, COSV52757227; called by muse, mutect2
- PCED1A | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100642969; called by muse, mutect2, varscan2
- PCSK4 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99961155; called by muse, mutect2
- PDE3B | c.1009T>C p.W337R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1236509517, COSV99963482; called by muse, mutect2, varscan2
- PDE4A | c.1652C>T p.T551I (on ENST00000380702 / NM_001111307.2; = p.T312I on NM_006202.3) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99535449; called by muse, mutect2, varscan2
- PEAK1 | c.4499T>C p.L1500P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100433574; called by muse, mutect2, varscan2
- PER1 | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100424957; called by muse, mutect2
- PEX1 | c.3471G>A p.M1157I | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99952477; called by muse, mutect2, varscan2
- PEX5L | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99830279; called by muse, mutect2, varscan2
- PGS1 | c.1216T>A p.Y406N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99428585; called by muse, mutect2, varscan2
- PHC1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101418726; called by muse, mutect2, varscan2
- PHF21B | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57558477; called by muse, mutect2, varscan2
- PHLDB1 | c.3685C>T p.R1229W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782338322, COSV100616876; called by muse, mutect2, varscan2
- PHYH | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1310532591, COSV99538427; called by muse, mutect2, varscan2
- PI4KA | c.4370C>T p.P1457L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV55405176; called by muse, mutect2, varscan2
- PIK3CG | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100783302; called by muse, mutect2, varscan2
- PIN4 | c.341C>T p.S114F (on ENST00000664196; = p.S89F on NM_006223.4) | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99512579; called by muse, mutect2, varscan2
- PKD2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99418059; called by muse, mutect2, varscan2
- PKD2L1 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV58395414; called by mutect2, varscan2
- PKHD1L1 | c.7247G>A p.G2416E | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1426935952, COSV65756779; called by muse, mutect2
- PKIB | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99236299; called by muse, mutect2, varscan2
- PKP2 | c.2003A>G p.K668R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV99298637; called by muse, mutect2, varscan2
- PLA1A | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV56331133; called by muse, mutect2, varscan2
- PLA1A | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846153; called by muse, mutect2, varscan2
- PLAAT5 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV57136461; called by muse, mutect2, varscan2
- PLB1 | c.621C>T p.V207= | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100580180; called by muse, mutect2, varscan2
- PLCB4 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as COSV99597273; called by muse, mutect2, varscan2
- PLCE1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs771124727, COSV53337446; called by muse, mutect2, varscan2
- PLEKHA5 | c.2668C>T p.L890F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV100164931; called by muse, mutect2, varscan2
- PLEKHG4B | c.2605G>A p.E869K (on ENST00000283426; = p.E1225K on NM_052909.5) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1193942050, COSV99361322; called by muse, mutect2, varscan2
- PNLIPRP1 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100724583; called by muse, mutect2
- PNMA1 | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99679335; called by muse, mutect2, varscan2
- PNPT1 | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV99569906, COSV99570624; called by muse, mutect2, varscan2
- POLE | c.2891C>T p.S964F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100268699; called by muse, mutect2, varscan2
- POLQ | c.5672C>T p.P1891L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV99953207; called by muse, mutect2, varscan2
- PRUNE2 | c.6748T>C p.W2250R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100945317, COSV65047666; called by muse, mutect2, varscan2
- PSD | c.2845-1G>A p.X949_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99194314; called by muse, mutect2
- PSEN2 | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100423371; called by muse, mutect2, varscan2
- PSG5 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs777232114, COSV61654964; called by muse, mutect2, varscan2
- PSMF1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs779635176, COSV55675984; called by muse, mutect2, varscan2
- PTK2 | c.1911T>G p.N637K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100571356; called by muse, mutect2, varscan2
- PTPDC1 | c.1225G>T p.E409* (on ENST00000375360 / NM_177995.3; = p.E461* on NM_152422.4) | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99998009; called by muse, mutect2, varscan2
- PTPRG | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99877433; called by muse, mutect2, varscan2
- PXDN | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs755443877, COSV53234178; called by muse, mutect2, varscan2
- QDPR | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.269); catalogued as COSV99846000; called by muse, mutect2, varscan2
- QSOX2 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1282168889, COSV62394906; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3124C>T p.P1042S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.015); catalogued as COSV99770633; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.134); catalogued as COSV99770634; called by muse, mutect2, varscan2
- RAB8A | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99959963; called by muse, mutect2, varscan2
- RADX | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV100998944; called by muse, mutect2, varscan2
- RALGAPA1 | c.5492G>A p.G1831E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99356558; called by muse, mutect2
- RAP1GAP2 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99624708; called by muse, mutect2, varscan2
- RAPGEF5 | c.656C>A p.A219D (on ENST00000401957 / NM_001367602.2; = p.A522D on NM_012294.5) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100688078; called by muse, mutect2, varscan2
- RARA | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs138717943, COSV99565583; called by muse, mutect2, varscan2
- RASEF | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100907062; called by muse, mutect2, varscan2
- RBBP6 | c.3503C>T p.S1168L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs748441167, COSV60503212; called by muse, mutect2, varscan2
- RBBP8NL | c.627+1G>A p.X209_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99437081; called by muse, mutect2, varscan2
- RCN3 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs574372719, COSV99571501; called by muse, mutect2, varscan2
- RERGL | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as COSV57462760; called by muse, mutect2, varscan2
- RFWD3 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV100736338; called by muse, mutect2
- RNF112 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1348436600, COSV101518366; called by muse, mutect2, varscan2
- RNF213 | c.7678C>T p.P2560S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100299874, COSV60405433; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as rs759521982, COSV100271959; called by muse, mutect2, varscan2
- RRAS | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.229); catalogued as rs1166281308, COSV99882163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RXFP2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV53641952; called by muse, mutect2, varscan2
- RYR2 | c.9217G>A p.E3073K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV100769234, COSV100773354; called by muse, mutect2, varscan2
- RYR2 | c.13042G>A p.E4348K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV63685778; called by muse, mutect2, varscan2
- SBF1 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs528597678, COSV100817751; called by muse, mutect2
- SCN8A | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100634381; called by muse, mutect2, varscan2
- SCN9A | c.2543C>T p.S848F (on ENST00000303354; = p.S837F on NM_002977.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100314611; called by muse, mutect2, varscan2
- SERPINA4 | c.979T>C p.Y327H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs747797123, COSV100097561; called by muse, mutect2, varscan2
- SETD5 | c.3227A>C p.Q1076P | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100201236; called by muse, mutect2
- SETX | c.5726C>T p.P1909L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866537385, COSV99811292; called by muse, mutect2, varscan2
- SH3GLB2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.394); catalogued as COSV100999422; called by muse, mutect2, varscan2
- SHOC1 | c.2105T>A p.I702N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100598138; called by muse, mutect2, varscan2
- SIGLEC14 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708039; called by muse, mutect2, varscan2
- SIGLEC8 | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs867265827, COSV100367445; called by muse, mutect2, varscan2
- SLA | c.637G>A p.G213R (on ENST00000338087 / NM_001045556.3; = p.G253R on NM_006748.4) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.165); catalogued as COSV99603926; called by muse, mutect2, varscan2
- SLC22A2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100871098; called by muse, mutect2, varscan2
- SLC22A25 | c.1395G>A p.R465= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as rs903338558, COSV100124053, COSV60594910; called by muse, mutect2, varscan2
- SLC22A8 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149538913, COSV60324208; called by muse, mutect2, varscan2
- SLC26A7 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1182719199, COSV99404611; called by muse, mutect2, varscan2
- SLC27A4 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100307530; called by muse, mutect2
- SLC35D1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV99338626; called by muse, mutect2, varscan2
- SLC36A2 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as COSV58864045; called by mutect2, varscan2
- SLC6A4 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV99911658; called by muse, mutect2, varscan2
- SLC7A9 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99195563; called by muse, mutect2, varscan2
- SLC8A3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); catalogued as COSV63521966, COSV63527980; called by muse, mutect2, varscan2
- SLC9A4 | c.2153G>A p.R718K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99763685; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2161G>A p.E721K (on ENST00000540229 / NM_001371097.1; = p.E660K on NM_001009562.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV101045394, COSV67443948; called by muse, mutect2, varscan2
- SLCO1C1 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs750496047, COSV99860216; called by muse, mutect2, varscan2
- SMG7 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV61632325; called by muse, mutect2, varscan2
- SNAI1 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.501); catalogued as COSV99724049; called by muse, varscan2
- SORCS1 | c.1429G>A p.G477R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545401, COSV99551315; called by muse, mutect2, varscan2
- SPAG6 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100510616; called by muse, mutect2, varscan2
- SPATA31D1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.133); catalogued as rs749219893, COSV100782536; called by muse, mutect2, varscan2
- SPHKAP | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100764259, COSV60878584; called by muse, mutect2, varscan2
- SPRED2 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1308584438, COSV62692711; called by muse, mutect2, varscan2
- SRCAP | c.4244T>C p.M1415T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs746462812, COSV99349688; called by muse, mutect2, varscan2
- SRL | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.408); catalogued as COSV101281375; called by muse, mutect2, varscan2
- SSUH2 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100436223; called by muse, mutect2, varscan2
- ST18 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV52508620; called by muse, mutect2, varscan2
- STAC2 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100336544; called by muse, mutect2
- SYCE1 | c.287T>A p.V96E (on ENST00000343131 / NM_001143764.3; = p.V60E on NM_130784.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100385995; called by muse, mutect2, varscan2
- SYTL4 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99343487; called by muse, mutect2, varscan2
- TACR1 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100538091; called by muse, mutect2, varscan2
- TAOK1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV55588528; called by muse, mutect2, varscan2
- TAS2R31 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.35); catalogued as rs1463971585, COSV101115937; called by muse, varscan2
- TBX20 | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1205975114, COSV101282445; called by muse, mutect2, varscan2
- TBX4 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99540809; called by muse, mutect2, varscan2
- TCF7L2 | c.1253C>T p.S418F (on ENST00000355995 / NM_001367943.1; = p.S395F on NM_030756.5) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53342827, COSV99526898; called by muse, mutect2, varscan2
- TCHHL1 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.406); catalogued as COSV64286543; called by muse, mutect2, varscan2
- TCTN2 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as rs1470729366, COSV100315450; called by muse, mutect2, varscan2
- TCTN2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs747637823, COSV57633911; called by muse, mutect2, varscan2
- TECTA | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV99881942; called by muse, mutect2, varscan2
- TENM1 | c.3599T>C p.L1200S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100950267, COSV100951297; called by muse, mutect2, varscan2
- TENM1 | c.3410C>T p.S1137F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV100951298, COSV64437646; called by muse, mutect2, varscan2
- TENM2 | c.7793C>T p.S2598F (on ENST00000518659 / NM_001122679.2; = p.S2359F on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs1344419465, COSV101317416, COSV101319499; called by muse, mutect2, varscan2
- TET3 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99996460, COSV99996683; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99305668; called by muse, mutect2, varscan2
- TGM2 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs755248877, COSV100821821; called by muse, varscan2
- TLN2 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV100170379; called by muse, mutect2, varscan2
- TLR5 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs756576692, COSV100643434, COSV60558883; called by muse, mutect2, varscan2
- TMEM132B | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as rs746605414, COSV100168718, COSV54747217; called by muse, mutect2, varscan2
- TMEM255B | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV64713248; called by muse, mutect2, varscan2
- TMEM259 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV99312416, COSV99313044; called by muse, mutect2, varscan2
- TMPRSS6 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs750274321, COSV60978533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNFRSF1A | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as rs760144597, COSV50599447; called by muse, mutect2, varscan2
- TNN | c.1325-1G>A p.X442_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99513362; called by muse, mutect2
- TOGARAM2 | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101091587; called by muse, mutect2, varscan2
- TONSL | c.3431G>A p.G1144D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV101340342; called by muse, mutect2, varscan2
- TONSL | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV101340343; called by muse, mutect2, varscan2
- TOR1A | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99400362; called by muse, mutect2, varscan2
- TP53BP2 | c.1430C>T p.S477F (on ENST00000343537 / NM_001031685.3; = p.S348F on NM_005426.2) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as COSV100636878; called by muse, mutect2, varscan2
- TP53INP1 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as COSV100711170; called by muse, mutect2, varscan2
- TPRX1 | c.1037A>G p.D346G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV100445974; called by muse, mutect2, varscan2
- TRIM71 | c.2363G>A p.G788D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101070535; called by muse, mutect2, varscan2
- TRIM75P | c.794C>A p.S265* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs1244266491, COSV72295830; called by muse, mutect2, varscan2
- TRPM3 | c.1950G>A p.M650I (on ENST00000357533 / NM_001366142.2; = p.M493I on NM_020952.6) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100679196; called by muse, mutect2, varscan2
- TSKS | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1313304722, COSV99883809; called by muse, mutect2, varscan2
- TSTD2 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100359235; called by muse, mutect2, varscan2
- TTBK1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52488097; called by muse, mutect2, varscan2
- TTC25 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV66367878; called by muse, mutect2, varscan2
- TTC3 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV100696173; called by muse, varscan2
- TTLL1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs267606265, COSV99840621; called by muse, varscan2
- TTLL8 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99838771; called by muse, mutect2, varscan2
- TTN | c.84085C>T p.L28029F (on ENST00000591111; = p.L20605F on NM_003319.4) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | PolyPhen probably damaging (0.999); catalogued as COSV100592321, COSV100635616; called by muse, mutect2
- TTN | c.12224G>A p.R4075K (on ENST00000591111; = p.R4029K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100598140, COSV60152392; called by muse, mutect2, varscan2
- TUBA3C | c.762A>T p.E254D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV101262857; called by muse, mutect2, varscan2
- TUBB2B | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.952); catalogued as COSV99455240; called by muse, mutect2, varscan2
- TUBB4A | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as rs752503674, COSV51154345, COSV99900216; called by muse, mutect2, varscan2
- U2AF2 | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100454542; called by muse, mutect2, varscan2
- UBN2 | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs767001232, COSV99944654; called by muse, mutect2, varscan2
- UGT2B11 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1334220353, COSV101485316; called by muse, mutect2
- ULK4 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778485045, COSV100095923; called by muse, mutect2, varscan2
- UNC13D | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs778208597, COSV99257841; called by muse, mutect2, varscan2
- UNC93B1 | c.1264T>C p.W422R | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99916608; called by muse, mutect2, varscan2
- USHBP1 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99394623; called by muse, mutect2, varscan2
- UTP3 | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99637122; called by muse, mutect2, varscan2
- UVRAG | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100638720; called by muse, mutect2, varscan2
- VCX | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100406433; called by muse, mutect2, varscan2
- VEGFD | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99938598; called by muse, mutect2, varscan2
- VRK3 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV100371906; called by muse, mutect2, varscan2
- WASF3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV100099765; called by muse, mutect2, varscan2
- WASHC1 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1436965573; called by muse, varscan2
- WDPCP | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1374748295, COSV99707350; called by muse, mutect2
- WDR49 | c.1162+1G>A p.X388_splice (on ENST00000308378 / NM_001366158.1; = p.X729_splice on NM_001348951.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as COSV57713333; called by muse, mutect2, varscan2
- WDR77 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99331022; called by muse, mutect2, varscan2
- WNT8B | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100649160, COSV59325275; called by muse, mutect2, varscan2
- XIRP2 | c.8594G>A p.G2865E (on ENST00000628543; = p.G3040E on NM_152381.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV54695150; called by muse, mutect2, varscan2
- XIRP2 | c.8996C>T p.P2999L (on ENST00000628543; = p.P3174L on NM_152381.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV99749023; called by muse, mutect2, varscan2
- XPO7 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99382245; called by muse, mutect2
- YAF2 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100586510; called by muse, mutect2, varscan2
- YARS2 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs555093151, COSV100256582; called by muse, mutect2, varscan2
- ZAP70 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV99386065; called by muse, mutect2, varscan2
- ZBTB22 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV99802847; called by muse, mutect2, varscan2
- ZMYM4 | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1485845269, COSV58909591; called by muse, mutect2, varscan2
- ZNF257 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs1408017047, COSV71307010, COSV71307493; called by muse, mutect2, varscan2
- ZNF341 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100678178; called by muse, mutect2, varscan2
- ZNF418 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101269044; called by muse, mutect2, varscan2
- ZNF433 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100795062; called by muse, mutect2, varscan2
- ZNF483 | c.671G>A p.W224* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100493166; called by muse, mutect2, varscan2
- ZNF599 | c.480T>G p.D160E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV100251368; called by muse, mutect2, varscan2
- ZNF606 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as COSV100357592; called by muse, mutect2, varscan2
- ZNF609 | c.1535T>C p.L512P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442024; called by muse, mutect2, varscan2
- ZNF615 | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100944042; called by muse, mutect2, varscan2
- ZNF618 | c.2467G>A p.E823K (on ENST00000374126 / NM_001318042.2; = p.E730K on NM_133374.2) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs774177716, COSV55919538; called by mutect2, varscan2
- ZNF683 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100853765; called by muse, mutect2, varscan2
- ZNF721 | c.2639C>T p.P880L (on ENST00000338977; = p.P892L on NM_133474.4) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV100167272; called by muse, mutect2, varscan2
- ZNF827 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1339127239, COSV65230365; called by muse, mutect2, varscan2
- ZNF846 | c.910C>A p.H304N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101194410; called by muse, mutect2, varscan2
- CD177 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CRYBG2 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GARNL3 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- IGKV2-24 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- IGKV3-15 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IL9R | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, varscan2
- IRF2 | c.82_87+26del p.X28_splice | Splice Site (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel
- KDM5C | c.2671_2688del p.L891_S896del | In Frame Del (DEL) | VAF 10/19 reads (53%) | called by mutect2, varscan2
- KIR2DS4 | c.81A>C p.R27S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- LSS | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MROH1 | c.2908G>A p.G970S | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MROH1 | c.2909G>A p.G970D | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NKTR | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); called by muse, mutect2
- OR4Q3 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUPT20HL2 | c.131A>T p.Y44F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TCF7L1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VOPP1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by mutect2, varscan2
- ZNF221 | c.1119_1121del p.K373_G374delinsN | In Frame Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- ZNRF3 | c.1556C>T p.S519F (on ENST00000544604 / NM_001206998.2; = p.S419F on NM_032173.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- ABCC12 | c.1410G>A p.E470= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100253424; called by muse, mutect2, varscan2
- ABCG2 | c.951G>A p.E317= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99420472; called by muse, mutect2, varscan2
- AC004997.1 | c.1257C>T p.I419= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs906024231, COSV100355922; called by muse, mutect2, varscan2
- ACACB | c.2541T>C p.I847= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100623402; called by muse, varscan2
- ACP5 | c.501C>T p.F167= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99520568; called by muse, mutect2, varscan2
- ACTBL2 | c.81C>T p.A27= | Silent (SNP) | VAF 99/121 reads (82%) | catalogued as COSV101379445; called by muse, mutect2, varscan2
- ACTRT3 | c.30C>T p.I10= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100377609; called by muse, mutect2, varscan2
- ADAMTS16 | c.2145G>A p.G715= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV56983008; called by muse, mutect2
- ADAMTS17 | c.1587G>A p.A529= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs767074176, COSV51496647, COSV99172726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.2559G>A p.G853= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs749540928, COSV99274671; called by muse, mutect2, varscan2
- ADGRL2 | c.1194C>T p.A398= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99592102; called by muse, mutect2, varscan2
- AFMID | c.558C>T p.N186= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs767826210, COSV100015153; called by muse, mutect2, varscan2
- ALDH9A1 | c.759C>T p.S253= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100699330; called by muse, mutect2
- ANK2 | c.1950C>T p.N650= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100004792; called by muse, mutect2, varscan2
- ANKRD10 | c.864C>T p.S288= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV57442512, COSV99941333; called by muse, mutect2, varscan2
- AP3B2 | c.1500C>T p.A500= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1231127689, COSV99917143; called by muse, mutect2, varscan2
- APOB | c.3516G>A p.E1172= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99268723; called by muse, mutect2, varscan2
- ATF7IP2 | c.954G>A p.L318= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100202872; called by muse, mutect2, varscan2
- ATL1 | c.1326C>T p.F442= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100613364; called by muse, mutect2, varscan2
- ATP7A | c.3333C>T p.F1111= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100431942; called by muse, mutect2, varscan2
- ATP8B1 | c.2673C>T p.I891= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs762815189, COSV99378036; called by muse, mutect2, varscan2
- AURKB | c.258C>T p.G86= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100298957; called by muse, mutect2, varscan2
- AURKC | c.861C>T p.I287= (on ENST00000302804 / NM_001015878.2; = p.I253= on NM_003160.3) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs565008485, COSV100249052; called by muse, mutect2, varscan2
- BBX | c.846G>A p.Q282= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs749737625, COSV100362396; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- C17orf97 | c.1179C>T p.P393= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100789403; called by muse, mutect2, varscan2
- C1orf127 | c.1353C>T p.S451= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV100983525; called by muse, mutect2, varscan2
- C3orf20 | c.1416G>C p.L472= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99514724; called by muse, mutect2
- CACTIN | c.210A>T p.R70= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99698970; called by muse, mutect2, varscan2
- CAMK2A | c.855G>A p.E285= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100652137; called by muse, mutect2, varscan2
- CCDC39 | c.633A>G p.Q211= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99870681; called by muse, mutect2
- CCDC57 | c.2178G>A p.G726= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV100492708; called by muse, mutect2, varscan2
- CCL17 | c.63C>T p.I21= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1301186930, COSV99537242; called by muse, mutect2, varscan2
- CCT8 | c.1353A>T p.A451= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99726211; called by muse, mutect2, varscan2
- CD1B | c.843G>A p.V281= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV63804171; called by muse, mutect2, varscan2
- CDC25B | c.993C>T p.P331= (on ENST00000245960 / NM_021873.3; = p.P317= on NM_004358.4) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99848442; called by muse, mutect2, varscan2
- CECR2 | c.570C>T p.V190= (on ENST00000342247 / NM_001290047.2; = p.V27= on NM_001290046.1) | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99379421; called by muse, mutect2
- CHRNA1 | c.732G>A p.L244= (on ENST00000261007 / NM_001039523.3; = p.L219= on NM_000079.4) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99650808; called by mutect2, varscan2
- CHST3 | c.1011G>A p.E337= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100910543; called by muse, mutect2
- CLEC2D | c.330T>C p.L110= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99325236; called by muse, mutect2, varscan2
- CLVS1 | c.171G>A p.R57= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs912154891, COSV100370879; called by muse, mutect2, varscan2
- COL5A3 | c.3744C>T p.P1248= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs780165005, COSV99318222; called by muse, mutect2, varscan2
- COL6A3 | c.3786G>A p.L1262= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs772017594, COSV99797685, COSV99802384; called by muse, mutect2, varscan2
- COL6A6 | c.2445T>C p.D815= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100651101; called by muse, mutect2, varscan2
- CRTAC1 | c.961C>T p.L321= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100086280, COSV54003559; called by muse, mutect2, varscan2
- CSMD1 | c.6831C>T p.F2277= (on ENST00000520002; = p.F2276= on NM_033225.6) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs371661443, COSV59378788; called by mutect2, varscan2
- CTNND1 | c.2682A>T p.G894= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100650331; called by muse, mutect2
- CX3CR1 | c.894G>A p.E298= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100843314; called by muse, mutect2, varscan2
- CYP1A2 | c.1176G>A p.R392= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100673952; called by muse, mutect2, varscan2
- CYP2C18 | c.336C>T p.I112= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV99609095; called by muse, mutect2, varscan2
- CYP46A1 | c.1086G>A p.R362= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99952936; called by muse, mutect2, varscan2
- CYP4Z1 | c.270C>T p.F90= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs1256153549, COSV100497967; called by muse, mutect2, varscan2
- DCAF15 | c.945C>T p.P315= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs141456591; called by muse, mutect2
- DENND2B | c.1380C>T p.S460= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs936218912, COSV100567975; called by muse, mutect2, varscan2
- DENND4B | c.780C>T p.T260= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100768963, COSV63412076; called by muse, mutect2, varscan2
- DMXL2 | c.6171A>T p.T2057= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99198963; called by muse, mutect2, varscan2
- DSCAML1 | c.1191C>T p.A397= (on ENST00000321322; = p.A337= on NM_020693.4) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100357479; called by muse, mutect2, varscan2
- EIF2AK1 | c.1443G>A p.G481= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99552458; called by muse, mutect2, varscan2
- ENTPD8 | c.363C>T p.F121= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100395775, COSV58161947; called by muse, mutect2, varscan2
- EP400 | c.126C>T p.F42= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs139666996, COSV57764426; called by muse, varscan2
- EP400 | c.9288C>T p.S3096= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs749537510, COSV57790382; called by mutect2, varscan2
- EPPK1 | c.1191C>T p.A397= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV101599989; called by muse, mutect2, varscan2
- EVPL | c.411C>T p.Y137= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs746582689, COSV56915214; called by muse, mutect2, varscan2
- EXOC3 | c.1635G>A p.E545= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100155728; called by muse, mutect2, varscan2
- FAM163B | c.147C>T p.F49= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs922908009; called by muse, mutect2, varscan2
- FAM187B | c.981G>A p.A327= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV61201679; called by muse, mutect2, varscan2
- FAM228A | c.435G>A p.Q145= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99722696; called by muse, mutect2, varscan2
- FAM47A | c.2226C>T p.F742= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100649863, COSV60496568; called by muse, mutect2, varscan2
- FAM47A | c.795G>A p.L265= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV60499914; called by muse, mutect2, varscan2
- FBXO9 | c.813C>T p.I271= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs748184630, COSV99762688; called by muse, mutect2, varscan2
- FER1L6 | c.45G>A p.K15= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101206252; called by muse, mutect2, varscan2
- FSHR | c.1683C>T p.I561= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs757713421, COSV58623930; called by muse, mutect2, varscan2
- G3BP1 | c.1245T>C p.T415= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100664072; called by muse, mutect2, varscan2
- GAD2 | c.1515C>T p.C505= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1368211057, COSV52151744, COSV99394282; called by muse, mutect2, varscan2
- GALNS | c.375G>A p.P125= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1395097829, COSV99243533; called by muse, mutect2, varscan2
- GALT | c.693T>A p.R231= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV101122799, COSV101122807; called by muse, mutect2
- GCKR | c.1209C>T p.I403= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs771143618, COSV53106491, COSV53106723; called by muse, mutect2, varscan2
- GCN1 | c.5658G>A p.L1886= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100326252; called by muse, mutect2, varscan2
- GLI1 | c.549G>A p.L183= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99954834; called by muse, mutect2
- GPR156 | c.1224G>A p.K408= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs746611047, COSV100251796; called by muse, mutect2, varscan2
- GRIN3A | c.1587G>A p.R529= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100701944; called by muse, mutect2, varscan2
- GRK6 | c.1338C>T p.P446= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100587100; called by muse, mutect2, varscan2
- GTF2H3 | c.120C>T p.A40= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs746780189, COSV57458364, COSV99967691; called by muse, mutect2, varscan2
- GULP1 | c.450G>A p.R150= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1384556595, COSV100771397; called by muse, mutect2, varscan2
- H6PD | c.1194C>T p.L398= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs112859991, COSV101072549; called by muse, mutect2
- HDAC5 | c.1014C>T p.V338= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99871179; called by muse, mutect2, varscan2
- HINFP | c.417C>T p.S139= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100640900; called by muse, mutect2, varscan2
- HTT | c.4935C>T p.S1645= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV61862505; called by muse, mutect2, varscan2
- ICAM1 | c.471G>A p.L157= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99321233; called by muse, mutect2, varscan2
- IDUA | c.267G>A p.R89= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99926582; called by muse, mutect2, varscan2
- IGHA1 | c.978G>A p.Q326= | Silent (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.210C>T p.I70= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs947808103; called by muse, mutect2, varscan2
- ILKAP | c.222G>T p.G74= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99611239; called by muse, mutect2, varscan2
- KCNU1 | c.219C>T p.I73= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1019048280, COSV67756258; called by muse, mutect2, varscan2
- KIF2B | c.1818G>A p.G606= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99276501; called by muse, mutect2, varscan2
- KIF2B | c.2004G>A p.V668= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs567529647, COSV99276503; called by mutect2, varscan2
- KIR2DL1 | c.18C>T p.V6= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV99383587, COSV99383783; called by muse, mutect2, varscan2
- KIR3DL2 | c.228C>T p.F76= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV99552134; called by muse, mutect2, varscan2
- KIRREL1 | c.2070C>T p.F690= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100780184; called by muse, mutect2, varscan2
- KLB | c.2484T>C p.T828= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs753443383, COSV57302090, COSV99962564; called by muse, mutect2, varscan2
- KLF15 | c.231G>A p.L77= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV56179140, COSV99955416; called by muse, mutect2, varscan2
- KLHL18 | c.708C>T p.F236= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV99231410; called by muse, mutect2, varscan2
- KRT33B | c.171G>A p.K57= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV99290901; called by muse, mutect2, varscan2
- KSR2 | c.1527C>T p.I509= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100196992; called by muse, mutect2, varscan2
- KYAT3 | c.384C>T p.I128= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs1232809066, COSV99557254; called by muse, mutect2, varscan2
- LILRA1 | c.672G>A p.K224= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV99252331; called by muse, varscan2
- LRP4 | c.2592C>T p.I864= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs750394691, COSV101066947; called by muse, mutect2, varscan2
- MACF1 | c.4599G>A p.Q1533= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1353786190, COSV99247546; called by muse, mutect2, varscan2
- MAGEB2 | c.51G>A p.K17= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100975766; called by muse, mutect2, varscan2
- MANEA | c.1179C>T p.R393= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100721715; called by muse, mutect2, varscan2
- MAP3K5 | c.1827C>A p.V609= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100753405, COSV62892735; called by muse, mutect2, varscan2
- MAP3K7CL | c.381C>T p.P127= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99726975; called by muse, mutect2, varscan2
- MBTD1 | c.1152C>T p.F384= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100899221, COSV64503113; called by mutect2, varscan2
- MFAP1 | c.897G>A p.K299= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99979957; called by muse, mutect2, varscan2
- MFN1 | c.165A>T p.V55= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99764769; called by muse, mutect2, varscan2
- MORC1 | c.1011G>A p.K337= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV51716290, COSV51719483; called by muse, mutect2, varscan2
- MROH5 | c.1476G>A p.R492= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV101436096, COSV71302131; called by muse, mutect2, varscan2
- MSH5 | c.927C>T p.L309= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100995005; called by muse, mutect2, varscan2
- MST1R | c.2352C>T p.S784= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs775519425, COSV56575494; called by muse, mutect2, varscan2
- MTCL1 | c.1176C>T p.I392= (on ENST00000306329 / NM_001378206.1; = p.I32= on NM_015210.4) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100095912; called by muse, mutect2, varscan2
- MUC16 | c.20763C>A p.S6921= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV101202229; called by muse, mutect2, varscan2
- MUC2 | c.2763G>A p.L921= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- MYCL | c.426C>T p.P142= (on ENST00000372816 / NM_001033081.3; = p.P172= on NM_005376.5) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV100862414; called by muse, mutect2, varscan2
- MYH14 | c.5109G>A p.E1703= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs759241600, COSV99224516; called by muse, mutect2, varscan2
- MYH4 | c.1239C>T p.F413= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs370061303; called by muse, mutect2, varscan2
- NACC1 | c.1029C>T p.L343= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99457367; called by mutect2, varscan2
- NANP | c.294C>T p.F98= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV59160283; called by muse, mutect2, varscan2
- NAPA | c.471C>T p.S157= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99645955; called by muse, mutect2, varscan2
- NAPA | c.93C>T p.L31= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs1358010196, COSV99645957; called by muse, mutect2, varscan2
- NAT1 | c.327C>T p.L109= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100306618; called by muse, mutect2, varscan2
- NAV2 | c.4512G>C p.P1504= (on ENST00000396087 / NM_001244963.2; = p.P1481= on NM_145117.5) | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100216966, COSV100217790; called by muse, mutect2, varscan2
- NCR1 | c.540G>A p.V180= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV52558546; called by muse, mutect2, varscan2
- NDUFB2 | c.168C>T p.F56= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV52595083, COSV99200007; called by muse, mutect2, varscan2
- NEB | c.9807G>A p.K3269= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99429041; called by muse, mutect2, varscan2
- NF1 | c.4689C>T p.N1563= (on ENST00000358273 / NM_001042492.3; = p.N1542= on NM_000267.3) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100648511; called by muse, mutect2, varscan2
- NF2 | c.225C>T p.L75= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100099812; called by muse, mutect2, varscan2
- NHS | c.972C>T p.L324= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs936213903, COSV101197093; called by muse, mutect2, varscan2
- NIPAL1 | c.1062A>G p.L354= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99784614; called by muse, mutect2, varscan2
- NLRC5 | c.2082G>A p.K694= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99348515; called by muse, mutect2, varscan2
- NLRX1 | c.144C>T p.A48= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs771901209, COSV99425075; called by muse, mutect2, varscan2
- NOLC1 | c.1797G>A p.Q599= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100893802; called by muse, mutect2, varscan2
- NPY2R | c.264C>T p.F88= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV61528313; called by muse, mutect2, varscan2
- NRP1 | c.2376G>T p.G792= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99589818; called by muse, mutect2, varscan2
- NSD1 | c.3015C>T p.L1005= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV61777403; called by muse, mutect2, varscan2
- NUP54 | c.1389C>T p.I463= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99345534; called by muse, mutect2, varscan2
- OMG | c.579C>T p.L193= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99907965; called by muse, mutect2
- OR13C8 | c.504C>T p.F168= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100623045, COSV58610845; called by muse, mutect2, varscan2
- OR2F2 | c.765G>A p.T255= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs866839513, COSV68832568; called by muse, mutect2, varscan2
- OR2L2 | c.612C>T p.I204= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100824390, COSV63559413; called by muse, mutect2, varscan2
- OR4C46 | c.891G>A p.R297= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV60218799; called by muse, mutect2, varscan2
- OR52E8 | c.327C>T p.F109= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs754251383, COSV101191293; called by muse, mutect2, varscan2
- OR5L1 | c.84C>T p.F28= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV61733933; called by muse, mutect2, varscan2
- OR9Q2 | c.927G>A p.K309= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs780450564, COSV100285575; called by muse, mutect2, varscan2
- P2RX2 | c.201C>T p.Y67= (on ENST00000343948 / NM_170683.4; = p.P45S on NM_012226.5) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100268697; called by muse, mutect2, varscan2
- PADI3 | c.1665G>T p.L555= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100968621; called by muse, mutect2, varscan2
- PAFAH1B3 | c.297C>T p.V99= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99360462; called by muse, mutect2, varscan2
- PARP6 | c.270G>A p.R90= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs763960583, COSV99536473; called by muse, mutect2, varscan2
- PARVB | c.75G>A p.R25= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100601486, COSV63109708; called by muse, mutect2, varscan2
- PCDHB2 | c.1011C>T p.V337= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99167092; called by muse, mutect2, varscan2
- PDCD11 | c.5089C>T p.L1697= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99588847; called by muse, mutect2, varscan2
- PGM2 | c.159C>T p.A53= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs896721550, COSV67939638; called by muse, mutect2, varscan2
- PHF21B | c.243C>T p.S81= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs1284232572, COSV100504149; called by muse, mutect2, varscan2
- PI4KA | c.4371C>T p.P1457= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99749300; called by muse, mutect2, varscan2
- PIK3CB | c.552C>T p.I184= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV56684324; called by muse, mutect2, varscan2
- PITPNB | c.324C>T p.F108= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100087098; called by muse, mutect2
- PKD1L1 | c.8208C>G p.L2736= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99221767; called by muse, mutect2, varscan2
- PLB1 | c.579G>A p.V193= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs1222410853, COSV100580179; called by muse, mutect2, varscan2
- PLXNB1 | c.2658C>T p.I886= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV99603623; called by muse, mutect2, varscan2
- PLXNB2 | c.4050C>T p.F1350= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1259523188, COSV63780845; called by muse, mutect2, varscan2
- PPP6R2 | c.945C>T p.F315= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs375687373; called by muse, mutect2, varscan2
- PRICKLE2 | c.2073C>T p.S691= (on ENST00000295902; = p.S635= on NM_198859.4) | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99898215; called by muse, mutect2, varscan2
- PRKD1 | c.2565C>T p.I855= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs143388121; ClinVar: likely benign; called by muse, mutect2, varscan2
- PROK2 | c.201C>T p.S67= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99817140; called by muse, mutect2, varscan2
- PRR16 | c.267C>T p.A89= (on ENST00000407149 / NM_001300783.2; = p.A66= on NM_016644.2) | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV101088465; called by muse, mutect2, varscan2
- PRUNE2 | c.2860C>T p.L954= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1257286043, COSV100945265, COSV100945319; called by muse, mutect2, varscan2
- PSD | c.1869G>A p.Q623= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99194316; called by muse, mutect2, varscan2
- PTK7 | c.2539T>C p.L847= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1435973488, COSV100030805; called by muse, mutect2, varscan2
- PTPRJ | c.3240C>T p.S1080= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101395828; called by muse, mutect2, varscan2
- PTPRR | c.978C>T p.F326= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99319126; called by muse, mutect2, varscan2
- PVR | c.1048C>T p.L350= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99495986; called by muse, mutect2, varscan2
- RAB2A | c.201C>T p.S67= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV52913350; called by muse, mutect2, varscan2
- RAB8A | c.51G>A p.S17= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV56292013, COSV99959961; called by muse, mutect2, varscan2
- RANBP17 | c.183C>T p.L61= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV101206202; called by muse, mutect2, varscan2
- RBM14 | c.163C>T p.L55= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100037023, COSV59559157; called by muse, mutect2, varscan2
- RFWD3 | c.1794C>T p.A598= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV63097854; called by muse, mutect2
- RHBDF2 | c.1002C>T p.I334= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100489745; called by muse, mutect2, varscan2
- RIBC1 | c.447G>A p.R149= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV99395152; called by muse, mutect2, varscan2
- RLIM | c.606C>T p.V202= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1452967575, COSV100223364; called by mutect2, varscan2
- RNF111 | c.126C>T p.P42= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs760339233, COSV100789101, COSV62088842; called by muse, mutect2, varscan2
- RNF169 | c.600G>A p.E200= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100213636; called by muse, mutect2, varscan2
- RXRB | c.1386C>T p.V462= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100554666; called by mutect2, varscan2
- S100A16 | c.171G>A p.K57= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs540582729, COSV100905909; called by muse, mutect2, varscan2
- SACS | c.5499C>T p.S1833= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV66543589, COSV66546350; called by muse, mutect2, varscan2
- SCN11A | c.4512C>T p.L1504= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100182122, COSV100182936, COSV56572233; called by muse, mutect2, varscan2
- SEC16B | c.162G>A p.G54= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100382051; called by muse, mutect2, varscan2
- SERPIND1 | c.333G>A p.G111= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99300562; called by muse, mutect2, varscan2
- SETD2 | c.4077C>T p.S1359= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100340282; called by muse, mutect2, varscan2
- SETDB1 | c.1956C>T p.F652= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs758794776, COSV99646091; called by muse, mutect2, varscan2
- SFTPD | c.159G>A p.R53= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100954579; called by muse, mutect2, varscan2
- SIPA1L3 | c.4545G>A p.K1515= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV55923126, COSV99730885; called by mutect2, varscan2
- SKIV2L | c.1617G>A p.K539= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100952896; called by muse, mutect2, varscan2
- SLAMF1 | c.798G>A p.T266= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs773246801, COSV52500829; called by muse, mutect2, varscan2
- SLC12A7 | c.1893C>T p.F631= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99370771; called by muse, mutect2, varscan2
- SLC15A2 | c.540G>A p.R180= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs756929100, COSV99815956; called by muse, mutect2, varscan2
- SLC35D1 | c.135C>T p.A45= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as rs1462951324, COSV99338621; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC35G5 | c.783C>T p.I261= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV99644684; called by muse, mutect2, varscan2
- SLC36A2 | c.1314C>T p.P438= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100079518; called by mutect2, varscan2
- SLC4A10 | c.3045C>T p.A1015= (on ENST00000446997 / NM_001354461.2; = p.A985= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99766429; called by muse, mutect2, varscan2
- SLCO1A2 | c.1635C>T p.S545= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100262971; called by muse, mutect2, varscan2
- SLCO1A2 | c.1014C>T p.F338= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100262974; called by muse, mutect2, varscan2
- SLCO1B1 | c.1596G>A p.R532= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV57006517; called by muse, mutect2, varscan2
- SMG6 | c.3084C>T p.V1028= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV99558944; called by muse, mutect2, varscan2
- SMG7 | c.3081C>T p.S1027= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100750208; called by muse, mutect2, varscan2
- SNAI1 | c.228C>T p.S76= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs758694399, COSV99724047; called by muse, varscan2
- SNAI1 | c.357T>C p.S119= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99724051; called by muse, varscan2
- SNTG2 | c.144G>A p.T48= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV57966251; called by muse, mutect2
- SON | c.4233T>A p.S1411= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99280289; called by mutect2, varscan2
- SORBS1 | c.2691C>T p.L897= (on ENST00000361941 / NM_001034954.2; = p.L547= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99529151; called by muse, mutect2, varscan2
- SOX17 | c.729G>A p.G243= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV99810903; called by muse, mutect2, varscan2
- SPAG6 | c.1188C>T p.L396= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100510610; called by muse, mutect2, varscan2
- SRGAP2 | c.2983C>T p.L995= (on ENST00000624873 / NM_001170637.4; = p.L996= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV99833413; called by muse, mutect2, varscan2
- STAM | c.1107C>T p.S369= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV101098420; called by mutect2, varscan2
- STX3 | c.63G>A p.A21= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1414917707, COSV100276350; called by muse, mutect2, varscan2
- SWT1 | c.708C>T p.I236= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1264533124, COSV62253980; called by muse, mutect2, varscan2
- SYNJ2 | c.1374G>A p.K458= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100840702, COSV62897116; called by muse, mutect2, varscan2
- SYT4 | c.831C>T p.I277= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV54900236; called by muse, mutect2, varscan2
- SZT2 | c.444G>A p.E148= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100161897; called by muse, mutect2, varscan2
54 further variants in this file (0 protein-altering or splice-affecting, 32 silent, 22 other) are not listed here.
